Gene-level copy-number profile of tumor specimen C3L-03374-01 from CPTAC case C3L-03374, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.9 years (30,274 days).
Specimen C3L-03374-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7ead9b77-58c2-4aa4-af57-3c6918463491.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03374-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/0fce1724-0c8d-4430-b049-a012327c37bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 538; copy number 1: 509; copy number 2: 17,979; copy number 3: 22,569; copy number 4: 14,009; copy number 5: 1,756; copy number 6: 75; copy number 7: 287; copy number 8: 530; copy number 9: 187; copy number 10: 35; copy number 11: 99; copy number 12: 45; copy number 14: 58; copy number 16: 17; copy number 17: 57; copy number 18: 2; copy number 19: 49; copy number 20: 3; copy number 21: 1; copy number 22: 12; copy number 23: 20; copy number 25: 1; copy number 28: 13; copy number 31: 1; copy number 33: 31; copy number 36: 18.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,581,339–161,678,654, 6 genes (within-gene range 0–4): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr1:248,573,801–248,635,091, 5 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr8:12,421,032–12,425,000, 1 gene: ALG1L12P.
- chr11:89,700,764–89,808,575, 13 genes: UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,466 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–159,483,376, 707 genes, copy number 8–11 (broad region; genes not listed).
- chr6:72,522,641–74,004,812, 38 genes, copy number 7: FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7.
- chr6:74,530,248–74,734,319, 1 gene, copy number 8 (within-gene range 6–8): AL356277.3.
- chr6:74,642,384–94,447,179, 249 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:12,290,071–12,296,180, 1 gene, copy number 25: DEFB131D.
- chr8:12,356,136–12,359,391, 1 gene, copy number 9: ZNF705CP.
- chr9:39,355,669–39,810,097, 14 genes, copy number 10: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene, copy number 10 (within-gene range 6–10): BX664615.2.
- chr9:61,854,148–62,096,920, 1 gene, copy number 8 (within-gene range 2–8): FAM27C.
- chr9:61,944,232–63,143,401, 38 genes, copy number 8: CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:65,668,805–66,254,464, 20 genes, copy number 10: CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12.
- chr11:28,679,183–29,989,328, 14 genes, copy number 7–9 (within-gene range 5–9): LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58.
- chr11:32,112,049–37,726,456, 96 genes, copy number 8–28 (broad region; genes not listed).
- chr11:57,299,638–57,477,534, 12 genes, copy number 7: TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1.
- chr11:66,682,497–73,662,819, 254 genes, copy number 7–36 (broad region; genes not listed).
- chr11:102,711,796–102,903,953, 11 genes, copy number 8: MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr11:103,109,410–103,479,863, 2 genes, copy number 11 (within-gene range 2–11): DYNC2H1, AP002961.1.
- chr14:106,850,885–106,879,812, 6 genes, copy number 7: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.

Autosomal genes at a single copy (total copy number 1): 509. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
